Somatic mutation profile of tumor specimen MMRF_2707_1_BM_CD138pos (aliquot MMRF_2707_1_BM_CD138pos_T1_KHS5U_L14440) from MMRF case MMRF_2707, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.3 years (22,383 days).
Specimen MMRF_2707_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e5eebc0-b343-4257-9cac-41697d0dfa59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2707_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2707_1_PB_WBC_C2_KHS5U_L14441; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9819237-3b4d-4409-9636-5b43308349ee

The open-access MAF lists 46 somatic variants for this specimen: 22 protein-altering or splice-affecting, 2 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 13, Intron 6, Splice Site 2, Silent 2, 5'UTR 1, RNA 1, Translation Start Site 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG3 | c.626T>A p.M209K | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as CM137934; called by muse, mutect2, varscan2
- CHRNA6 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866356960; called by muse, mutect2
- IGHV2-70 | c.166A>G p.S56G | Missense Mutation (SNP) | VAF 79/120 reads (66%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs759335337; called by muse, varscan2
- NEB | c.2340G>C p.E780D | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.992); catalogued as COSV51467698; called by muse, mutect2, varscan2
- NOX3 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747174417; called by muse, mutect2, varscan2
- SCAF8 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 60/125 reads (48%) | catalogued as COSV65790516, COSV65794278; called by muse, mutect2, varscan2
- TEX55 | c.1223T>C p.V408A | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs140682900; called by muse, mutect2, varscan2
- VWDE | c.3274+1G>A p.X1092_splice | Splice Site (SNP) | VAF 13/32 reads (41%) | catalogued as rs747375575; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1670A>G p.Q557R | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- AJM1 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- DGLUCY | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EML1 | c.1552T>G p.L518V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- FRMD1 | c.1573C>T p.L525F | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- GNRHR | c.532T>A p.F178I | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- NOX4 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- RGS12 | c.190A>T p.I64L | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by mutect2, varscan2
- SEMA6D | c.398T>C p.V133A | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SVOP | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TELO2 | c.1083C>G p.S361R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TNR | c.1964-1G>T p.X655_splice | Splice Site (SNP) | VAF 57/128 reads (45%) | called by muse, varscan2
- TRIM25 | c.305A>C p.N102T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBXN2A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NUDT16 | c.69C>T p.C23= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- ZFAND5 | c.57C>T p.G19= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as rs370085780; called by muse, mutect2
- ABL2 | c.*2919T>C | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- ADH7 | c.*205T>C | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- BMPR1B | chr4:95156193 C>G | 3'Flank (SNP) | VAF 46/104 reads (44%) | called by muse, mutect2, varscan2
- CALHM5 | c.*4665T>G | 3'UTR (SNP) | VAF 51/97 reads (53%) | called by muse, mutect2, varscan2
- DDX21 | c.*1749C>T | 3'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- DESI2 | c.*495A>T | 3'UTR (SNP) | VAF 92/170 reads (54%) | called by muse, mutect2, varscan2
- DSC1 | c.*393A>G | 3'UTR (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- KEL | c.1315-104C>A | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- LRRC38 | c.-15G>T | 5'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2
- MDS2 | n.672A>C | RNA (SNP) | VAF 72/172 reads (42%) | called by muse, varscan2
- MYT1L | c.*833T>A | 3'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- NSD2 | c.1882-2399G>A | Intron (SNP) | VAF 44/97 reads (45%) | catalogued as rs965291308; called by muse, mutect2, varscan2
- PCDHB16 | c.*297T>C | 3'UTR (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- PPM1A | c.952+1740T>C | Intron (SNP) | VAF 31/66 reads (47%) | catalogued as rs1001922540; called by muse, mutect2, varscan2
- PTGER3 | c.*928del | 3'UTR (DEL) | VAF 5/19 reads (26%) | catalogued as rs1276878927; called by mutect2, pindel, varscan2
- RUNX1T1 | c.88+13074A>C | Intron (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- SGK1 | c.152+48C>A | Intron (SNP) | VAF 49/79 reads (62%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.*1142G>T | 3'UTR (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- STAT1 | c.*1527G>C | 3'UTR (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- TGIF2 | c.*2307T>G | 3'UTR (SNP) | VAF 56/116 reads (48%) | called by muse, varscan2
- ZNF148 | c.*650A>G | 3'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- ZNF561 | c.25+153T>A | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, varscan2
